Somatic mutation profile of tumor specimen 0DJC39 from CCDI case PBBWIU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.3 years (3,032 days).
Specimen 0DJC39: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cdfab1d-2f9b-4b4f-9046-3687be77526c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJBLP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54c04da8-493c-4f51-83b6-8f50bc34e55a

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 5'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRINP3 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 334/464 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs199983605, COSV66532306, COSV66534597; called by muse, mutect2, varscan2
- TENT5D | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 240/258 reads (93%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57637979; called by muse, mutect2, varscan2
- AIFM2 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LRIF1 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 273/597 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- MBOAT7 | c.927C>A p.F309L | Missense Mutation (SNP) | VAF 264/552 reads (48%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.653); called by mutect2, varscan2
- USP14 | c.1020T>A p.N340K | Missense Mutation (SNP) | VAF 127/281 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CREB3L4 | c.99C>A p.P33= | Silent (SNP) | VAF 31/441 reads (7%) | called by muse, mutect2
- MYCBPAP | c.864C>A p.L288= | Silent (SNP) | VAF 52/781 reads (7%) | called by muse, mutect2
- RSPH10B | c.243C>T p.L81= | Silent (SNP) | VAF 202/420 reads (48%) | called by muse, mutect2, varscan2
- USP17L17 | c.9C>T p.D3= | Silent (SNP) | VAF 188/2028 reads (9%) | catalogued as rs1282723476; called by muse, varscan2
- CXCL9 | c.-48A>G | 5'UTR (SNP) | VAF 100/198 reads (51%) | called by muse, varscan2
- DCHS2 | n.7987G>A | RNA (SNP) | VAF 131/306 reads (43%) | called by muse, mutect2, varscan2
- TPT1 | c.-80G>A | 5'UTR (SNP) | VAF 43/129 reads (33%) | called by muse, mutect2, varscan2
